Somatic mutation profile of tumor specimen 0DLRHT from CCDI case PBBZKE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 6.3 years (2,301 days).
Specimen 0DLRHT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7747849-753f-4e6f-96b1-5e154eee91ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLRHJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec9b4a6e-8c4d-47ce-aa79-795163fc9a64

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNER | c.1183T>C p.Y395H | Missense Mutation (SNP) | VAF 216/568 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.022); called by muse, varscan2
- EGFLAM | c.2769T>G p.G923= (on ENST00000354891 / NM_001205301.2; = p.G915= on NM_152403.4) | Silent (SNP) | VAF 156/574 reads (27%) | called by muse, varscan2
